Somatic mutation profile of tumor specimen PCProject_0186_T1_WES (aliquot PCProject_0186_T1_WES_1) from CMI case PCProject_0186, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.3 years (18,746 days).
Specimen PCProject_0186_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba7d497e-a272-403f-950c-c5f9247e0ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0186_SALIVA (Saliva), aliquot PCProject_0186_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df3ea350-f044-4dab-aa92-dd0ba011f845

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHYHIPL | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV65849421; called by muse, mutect2, varscan2
- ANK3 | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CABS1 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- NDST4 | c.2482C>A p.P828T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- NOTCH3 | c.5036G>T p.G1679V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PIEZO1 | c.5381del p.F1794Sfs*127 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- TAB2 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF385B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.2154C>A p.A718= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- INHBA | c.507C>A p.T169= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- IP6K1 | c.210C>G p.T70= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs371433710; called by muse, mutect2
- RREB1 | c.4305C>T p.P1435= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- TAF1L | c.2838T>G p.V946= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99644581; called by muse, mutect2
- TBC1D16 | c.2097C>T p.I699= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs746141447; called by muse, mutect2, varscan2
- PLCH2 | c.2959+159C>T | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1558038183; called by muse, mutect2, varscan2
- PYGL | c.660+36A>C | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, varscan2
- STX4 | chr16:31033468 G>T | 5'Flank (SNP) | VAF 23/144 reads (16%) | called by muse, varscan2
